TARGET case TARGET-30-PANRHJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74c365db-15be-5b7c-b3a0-bb4dd6dbd56e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 416 days (1.1 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.1; Tissue or organ of origin: Thorax, NOS; Classification of tumor: primary; Age at diagnosis: 3.1 years (1,117 days); Year of diagnosis: 2005; Days to last follow up: 416 days (1.1 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 363 days; Progression or recurrence anatomic site: Bone, NOS; Days to first event: 363 days; First event: Relapse.
- Days to follow up: 363 days; Progression or recurrence anatomic site: Bone marrow.
- Days to follow up: 416 days (1.1 years); Year of follow up: 2006.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PANRHJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PANRHJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 416
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.51
- Histology: Unfavorable
- ICDO Description: Thorax, NOS Axilla, NOS Chest, NOS Chest wall, NOS Intrathoracic site, NOS Thoracic wall, NOS Infraclavicular region, NOS Scapular region, NOS
- Site of Relapse: Bone; Bone Marrow; Other Metastatic Sites
